Somatic mutation profile of tumor specimen MMRF_2666_1_BM_CD138pos (aliquot MMRF_2666_1_BM_CD138pos_T1_KHS5U_L13786) from MMRF case MMRF_2666, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.0 years (22,659 days).
Specimen MMRF_2666_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e40e28ce-8c5c-4c60-9058-0cea954b0ef9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2666_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2666_1_PB_WBC_C3_KHS5U_L13787; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b105176-3b9d-4c9a-8faf-e85d53472863

The open-access MAF lists 156 somatic variants for this specimen: 59 protein-altering or splice-affecting, 26 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, 3'UTR 39, Silent 26, Intron 20, 5'UTR 5, Frame Shift Del 4, 3'Flank 3, RNA 2, 5'Flank 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXCR4 | c.1013C>G p.S338* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs104893626, CM066016, COSV54009912, COSV54010290; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131690851, CS071257, COSV57306967; ClinVar: pathogenic; called by muse, mutect2
- AC011448.1 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs527888583; called by muse, mutect2, varscan2
- ANGPTL4 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369127747; called by muse, mutect2, varscan2
- BEND4 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs777208498, COSV101549717; called by muse, mutect2, varscan2
- COQ2 | c.653C>G p.T218S | Missense Mutation (SNP) | VAF 97/255 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.042); catalogued as COSV61021640; called by muse, mutect2, varscan2
- CXXC1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 72/383 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1233085169; called by muse, mutect2, varscan2
- DAAM2 | c.2387G>T p.R796I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV51302675; called by muse, mutect2, varscan2
- EFNA2 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1267476264; called by muse, mutect2, varscan2
- HIRA | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs782416995, COSV54274726; called by muse, mutect2, varscan2
- IGLV3-1 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 106/140 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs192317432; called by muse, mutect2
- IGLV3-1 | c.322G>C p.A108P | Missense Mutation (SNP) | VAF 105/138 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs541322241; called by muse, mutect2
- IGLV4-60 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs375528362; called by muse, mutect2, varscan2
- IGLV4-60 | c.272G>C p.S91T | Missense Mutation (SNP) | VAF 107/294 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs187948661; called by muse, mutect2, varscan2
- INPP5D | c.874C>T p.R292W (on ENST00000445964 / NM_001017915.3; = p.R291W on NM_005541.5) | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs1426795737, COSV64038622; called by muse, mutect2, varscan2
- IRF6 | c.358del p.Q120Rfs*47 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as CM054761, CM092341, COSV65418762; called by mutect2, pindel, varscan2
- KALRN | c.5719G>C p.E1907Q (on ENST00000360013 / NM_001024660.4; = p.E210Q on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.709); catalogued as COSV52262003; called by muse, mutect2, varscan2
- KDR | c.2882G>T p.R961L | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV55769273; called by muse, varscan2
- KIF16B | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 142/330 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as rs773625540; called by muse, mutect2, varscan2
- LYPD6B | c.67G>A p.A23T (on ENST00000409029 / NM_001317004.1; = p.A47T on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs369164244; called by muse, mutect2, varscan2
- MAX | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, mutect2, varscan2
- MGA | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 66/448 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as rs1254354796; called by muse, mutect2, varscan2
- MLLT1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.713); catalogued as rs542573805; called by muse, varscan2
- MN1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as rs1214027780, COSV56562951; called by muse, mutect2, varscan2
- MYCN | c.1313A>T p.H438L | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV104384427; called by muse, mutect2, varscan2
- PCDH11X | c.2713C>A p.L905I | Missense Mutation (SNP) | VAF 192/222 reads (86%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.669); catalogued as COSV100007824; called by muse, mutect2, varscan2
- PCDHA11 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as rs782622577, COSV56537323, COSV56541662; called by muse, mutect2
- SPTBN2 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769185550; called by muse, mutect2, varscan2
- TMEM196 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68256875; called by muse, mutect2, varscan2
- ZFPM2 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 95/381 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.34); catalogued as rs1454243628; called by muse, mutect2, varscan2
- ZNF782 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1369897210; called by muse, mutect2, varscan2
- AUNIP | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 94/249 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CA9 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CNDP2 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- DLG1 | c.927_929del p.R310del | In Frame Del (DEL) | VAF 16/118 reads (14%) | called by pindel, varscan2
- IRX6 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRBA | c.2966G>T p.G989V | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAML1 | c.1767G>C p.Q589H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MYO5A | c.137del p.K46Rfs*7 | Frame Shift Del (DEL) | VAF 25/163 reads (15%) | called by mutect2, pindel, varscan2
- NWD2 | c.325T>G p.C109G | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR2T10 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ORAI1 | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEX2 | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2G6 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRSS55 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SAMM50 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); called by muse, mutect2
- SDK2 | c.5102C>T p.A1701V | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SETD4 | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SH3PXD2B | c.620A>C p.E207A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SLBP | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC7A4 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SOX14 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- STEAP3 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.201); called by muse, varscan2
- STK36 | c.2819G>C p.C940S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- TTLL7 | c.1721_1725del p.K574Rfs*7 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- VIRMA | c.3097G>T p.V1033F | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XDH | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZFYVE16 | c.4491A>C p.Q1497H | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF609 | c.335del p.S112Mfs*42 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | called by mutect2, pindel, varscan2
- APOB | c.7129C>T p.L2377= | Silent (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- COL7A1 | c.1128G>T p.G376= | Silent (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- CRACDL | c.1101C>T p.D367= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV101194002; called by muse, mutect2
- ENTPD2 | c.516T>C p.T172= | Silent (SNP) | VAF 38/257 reads (15%) | called by muse, mutect2, varscan2
- FAT3 | c.11379G>A p.P3793= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as rs779979255, COSV53124644; called by muse, mutect2, varscan2
- FBXO11 | c.1665T>C p.G555= (on ENST00000403359 / NM_001190274.2; = p.G471= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.156A>G p.G52= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as rs1232476476; called by muse, mutect2, varscan2
- IGHV2-70 | c.60G>A p.Q20= | Silent (SNP) | VAF 37/47 reads (79%) | catalogued as rs374015637; called by muse, mutect2, varscan2
- IGLV1-47 | c.324T>C p.C108= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as rs1430479178; called by muse, varscan2
- KCNH1 | c.1944C>T p.F648= (on ENST00000271751 / NM_172362.3; = p.F621= on NM_002238.4) | Silent (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- KDR | c.2883G>T p.R961= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as rs56159068; called by muse, varscan2
- MUC22 | c.4356C>A p.G1452= | Silent (SNP) | VAF 30/816 reads (4%) | called by muse, mutect2
- MYOM2 | c.1083C>T p.G361= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs369466586; called by muse, mutect2, varscan2
- OGDH | c.1455C>T p.Y485= | Silent (SNP) | VAF 66/411 reads (16%) | catalogued as rs766321374, COSV56045309; called by muse, mutect2, varscan2
- POLRMT | c.2997C>T p.Y999= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs764005399, COSV52112561; called by muse, mutect2, varscan2
- PTPRK | c.3352A>C p.R1118= (on ENST00000368215 / NM_001291984.2; = p.R1119= on NM_002844.4) | Silent (SNP) | VAF 224/335 reads (67%) | called by muse, mutect2, varscan2
- RHBDL1 | c.1017G>A p.L339= (on ENST00000219551 / NM_001318733.2; = p.L274= on NM_001278720.2) | Silent (SNP) | VAF 12/193 reads (6%) | called by muse, mutect2
- SERPINA11 | c.292C>T p.L98= | Silent (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- SLC22A14 | c.1722C>T p.S574= | Silent (SNP) | VAF 147/227 reads (65%) | catalogued as rs753783415; called by muse, mutect2, varscan2
- SLC41A3 | c.141C>T p.S47= | Silent (SNP) | VAF 26/251 reads (10%) | catalogued as rs142041472, COSV59986869; called by muse, mutect2, varscan2
- SPATA31D1 | c.2814C>T p.S938= | Silent (SNP) | VAF 69/398 reads (17%) | catalogued as COSV100783105; called by muse, mutect2, varscan2
- STK4 | c.108T>C p.L36= | Silent (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
- TEX49 | c.90A>G p.E30= | Silent (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- TMC5 | c.2430C>T p.Y810= (on ENST00000396229 / NM_001105248.1; = p.Y564= on NM_024780.5) | Silent (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- TRRAP | c.3093T>C p.I1031= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as rs1187165148; called by muse, mutect2, varscan2
- UGT3A2 | c.1116G>A p.Q372= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56931868; called by muse, mutect2, varscan2
- ACP6 | c.-344G>T | 5'UTR (SNP) | VAF 35/268 reads (13%) | catalogued as COSV65077234; called by muse, mutect2, varscan2
- AMOTL2 | c.*4A>T | 3'UTR (SNP) | VAF 77/417 reads (18%) | called by muse, mutect2, varscan2
- ARL8A | c.-86C>A | 5'UTR (SNP) | VAF 12/100 reads (12%) | called by mutect2, varscan2
- ATP10B | c.*1219C>T | 3'UTR (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- ATXN1 | c.*4099C>T | 3'UTR (SNP) | VAF 31/196 reads (16%) | called by muse, mutect2, varscan2
- BEST1 | c.1740-536C>T | Intron (SNP) | VAF 43/78 reads (55%) | catalogued as rs1240273386; called by muse, mutect2, varscan2
- BMP6 | c.*768G>C | 3'UTR (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2, varscan2
- C12orf77 | n.529C>T | RNA (SNP) | VAF 145/481 reads (30%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.448-131C>G | Intron (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- CAAP1 | c.*1542A>G | 3'UTR (SNP) | VAF 56/93 reads (60%) | called by muse, mutect2, varscan2
- CACNA1E | c.*2006C>T | 3'UTR (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- CD46 | c.*1341C>G | 3'UTR (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- CEP97 | c.*1790del | 3'UTR (DEL) | VAF 14/70 reads (20%) | catalogued as rs545912852; called by mutect2, pindel, varscan2
- CLEC12A | c.191-132A>C | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- COG2 | chr1:230693998 T>A | 3'Flank (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- CPSF2 | c.*542T>A | 3'UTR (SNP) | VAF 10/76 reads (13%) | called by mutect2, varscan2
- DCX | c.*4714T>C | 3'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- DDX52 | c.*3044T>C | 3'UTR (SNP) | VAF 21/69 reads (30%) | called by muse, mutect2, varscan2
- GABRD | c.470+15_470+26del | Intron (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel
- GNB1L | c.*4210_*4213del | 3'UTR (DEL) | VAF 51/280 reads (18%) | called by mutect2, pindel, varscan2
- H4C8 | c.*59C>T | 3'UTR (SNP) | VAF 105/395 reads (27%) | catalogued as COSV99175496; called by muse, mutect2, varscan2
- HNRNPA1 | c.907+105T>A | Intron (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- HOXB13 | c.*988T>A | 3'UTR (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- IDI1 | chr10:1035857 C>T | 3'Flank (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- IGHV1-46 | c.-95A>C | 5'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, varscan2
- IRAK1BP1 | c.*4559G>A | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- KANK1 | c.3246-882A>T | Intron (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- KCNN3 | c.933+9337G>A | Intron (SNP) | VAF 144/352 reads (41%) | catalogued as rs1415787795, COSV55211982; called by muse, mutect2, varscan2
- KNL1 | c.*1446A>G | 3'UTR (SNP) | VAF 63/231 reads (27%) | called by muse, mutect2, varscan2
- LRRC15 | c.*3748G>A | 3'UTR (SNP) | VAF 70/222 reads (32%) | called by muse, mutect2, varscan2
- LTB | c.209-90A>T | Intron (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
- MCHR2 | c.*283T>C | 3'UTR (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- MDGA1 | c.*3432T>G | 3'UTR (SNP) | VAF 48/257 reads (19%) | called by muse, mutect2, varscan2
- MDH1 | c.-3A>G | 5'UTR (SNP) | VAF 151/364 reads (41%) | catalogued as rs201441090; called by muse, mutect2, varscan2
- MINDY4B | c.1240+93G>A | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- MRAP2 | c.*628C>T | 3'UTR (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- MVB12A | chr19:17420021 ins CA | 5'Flank (INS) | VAF 44/56 reads (79%) | catalogued as rs1555735882; called by muse*, mutect2, varscan2*
- MYH3 | c.349-32A>C | Intron (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- MYO1B | c.*1047A>G | 3'UTR (SNP) | VAF 35/146 reads (24%) | called by muse, mutect2, varscan2
- NEGR1 | c.*3775G>A | 3'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- NMNAT3 | chr3:139560307 ins T | 3'Flank (INS) | VAF 10/102 reads (10%) | called by mutect2, pindel
- NSD2 | c.1881+2677C>T | Intron (SNP) | VAF 39/262 reads (15%) | called by muse, mutect2, varscan2
- OARD1 | c.*2059C>G | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- PAAF1 | c.47+102C>T | Intron (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- PLB1 | c.2321+917C>T | Intron (SNP) | VAF 25/165 reads (15%) | catalogued as rs890773400; called by muse, mutect2, varscan2
- PLCB1 | c.*1752A>C | 3'UTR (SNP) | VAF 21/43 reads (49%) | catalogued as rs1488826054; called by muse, mutect2, varscan2
- PTPRE | c.1143+21G>T | Intron (SNP) | VAF 36/242 reads (15%) | catalogued as COSV54560975; called by muse, mutect2, varscan2
- RAD18 | c.*1337G>T | 3'UTR (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-1980G>C | Intron (SNP) | VAF 30/179 reads (17%) | catalogued as COSV57628299; called by muse, mutect2, varscan2
- RPS29 | chr14:49586402 C>A | 5'Flank (SNP) | VAF 78/405 reads (19%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.-129C>T | 5'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- S1PR5 | c.*7C>T | 3'UTR (SNP) | VAF 18/97 reads (19%) | catalogued as rs758065591, COSV100330793; called by muse, mutect2, varscan2
- SCN2B | c.*735C>A | 3'UTR (SNP) | VAF 25/163 reads (15%) | called by muse, mutect2, varscan2
- SGMS1 | c.*998_*1003del | 3'UTR (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- SLC19A2 | c.1224-22C>T | Intron (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- SLC6A1 | c.*148G>A | 3'UTR (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2
- SMAD6 | c.*13C>T | 3'UTR (SNP) | VAF 15/142 reads (11%) | catalogued as rs769889636; called by muse, mutect2, varscan2
- SMARCA2 | c.*566A>G | 3'UTR (SNP) | VAF 44/163 reads (27%) | called by muse, mutect2, varscan2
- SNTG1 | c.1192-89A>C | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- SPOCK2 | c.*731C>T | 3'UTR (SNP) | VAF 130/270 reads (48%) | catalogued as rs903837145, COSV58038323; called by muse, mutect2, varscan2
- TAFA5 | c.*1924T>C | 3'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- TAOK3 | c.*691G>A | 3'UTR (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- TENT4A | c.*1093C>T | 3'UTR (SNP) | VAF 32/219 reads (15%) | catalogued as rs1017597555; called by muse, mutect2, varscan2
- TMEM135 | c.*151A>G | 3'UTR (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.308-13C>G | Intron (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- TPM2 | c.640-19G>A | Intron (SNP) | VAF 24/210 reads (11%) | catalogued as rs1455692788; called by muse, mutect2, varscan2
- TSPEAR | c.1566+1396C>A | Intron (SNP) | VAF 49/288 reads (17%) | called by muse, mutect2, varscan2
- TTC37 | c.*278C>T | 3'UTR (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- VGLL3 | c.*726G>T | 3'UTR (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- XIST | n.9982A>C | RNA (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- ZNF260 | c.*950C>G | 3'UTR (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
